Surgical pathology report (de-identified scan), TCGA case TCGA-XF-AAN8, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-AAN8-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT

Collected
Ordered by

Location

DIAGNOSIS:

RADICAL CYSTECTOMY WITH ILEAL CONDUIT AND BILATERAL PELVIC LYMPH NODE DISSECTION:

RIGHT DISTAL URETER (A):

FROZEN SECTION DIAGNOSIS:

- NO TUMOR IDENTIFIED
- FINAL DIAGNOSIS:**
- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT DISTAL STENTED URETER (B):

FROZEN SECTION DIAGNOSIS:

- HYDROURETER, NO TUMOR IDENTIFIED
- FINAL DIAGNOSIS:**
- BENIGN URETER WITH HYDROURETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT STENTED URETER (C):

FROZEN SECTION DIAGNOSIS:

- REACTIVE ATYPIA
- NO HIGH GRADE DYSPLASIA IDENTIFIED
- FINAL DIAGNOSIS:**
- BENIGN URETER WITH REACTIVE UROTHELIAL ATYPIA
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

OLD SCAR PERIVESICAL NODE, BLADDER, URETHRAL MARGIN, VAGINA STRIP (D):

BLADDER:

GROSS DIAGNOSIS:

- TUMOR CLOSELY APPROACHES DEEP RADIAL MARGIN

FINAL DIAGNOSIS:

- UROTHELIAL CARCINOMA, HIGH GRADE, NUCLEAR GRADE 4/4 WITH SQUAMOUS DIFFERENTIATION, INVOLVING POSTERIOR BLADDER WALL AND EXTENDING INTO LEFT URETER-VESICLE JUNCTION AND LEFT URETER
- TUMOR EXTENDS THROUGHOUT THE ENTIRE BLADDER WALL AND DEEPLY INFILTRATES INTO PERIVESICAL SOFT TISSUE
- FOCAL CARCINOMA IN SITU (FLAT LESION) ASSOCIATED WITH INVASIVE TUMOR
- TUMOR CLOSELY COMES WITHIN 1 MM OF THE POSTERIOR SOFT TISSUE RESECTION MARGIN, FINAL SOFT TISSUE MARGIN (SEE PART E) NEGATIVE FOR TUMOR
- ALL OTHER MARGINS, BILATERAL URETERS (2 LEFT AND 2 RIGHT), URETHRAL, AND VAGINAL MUCOSA MARGIN NEGATIVE FOR TUMOR
- EXTENSIVE FOLLICULAR CYSTITIS PRESENT
- SKIN WITH ASSOCIATED SCAR, NO TUMOR IDENTIFIED

RIGHT AND LEFT PERIVESICAL LYMPH NODES (D):

- NO TUMOR IDENTIFIED IN SIX PERIVESICAL LYMPH NODES (0/6)

LEFT PELVIC FLOOR MARGIN (E):

- BENIGN FIBRO CONNECTIVE TISSUE AND MUSCLE
- NO TUMOR IDENTIFIED

RIGHT PARACAVAL LYMPH NODES (F):

- NO MALIGNANCY IDENTIFIED IN FIVE LYMPH NODES EXAMINED (0/5)

RIGHT COMMON ILIAC LYMPH NODES (G):

- NO MALIGNANCY IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

RIGHT LYMPH NODE OF CLOQUET (H):

- BENIGN FIBRO CONNECTIVE TISSUE AND ADIPOSE TISSUE
- NO LYMPHOID TISSUE IDENTIFIED (0/0)

ICD O-3

Carcinoma, urothelial NOS 8120/3

Site: Bladder, posterior wall
C67.4

JW 3/26/14

20% squamous, per TSS.

[page 2 of 6]
SURGICAL PATHOLOGY REPORT

Collected
Ordered by

Location

LEFT PARA AORTIC LYMPH NODES (I):

- BENIGN FIBRO CONNECTIVE TISSUE AND ADIPOSE TISSUE
- NO LYMPHOID TISSUE IDENTIFIED (0/0)

LEFT COMMON ILIAC LYMPH NODES (J):

- NO MALIGNANCY IDENTIFIED IN TEN LYMPH NODES EXAMINED (0/10)

RIGHT OBTURATOR/HYPOGASTRIC LYMPH NODES (K):

- NO MALIGNANCY IDENTIFIED IN 16 LYMPH NODES EXAMINED (0/16)

RIGHT EXTERNAL ILIAC LYMPH NODES (L):

- NO MALIGNANCY IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

PRE SACRAL LYMPH NODES (M):

- NO MALIGNANCY IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

LEFT LYMPH NODE OF CLOQUET (N):

- NO MALIGNANCY IDENTIFIED IN FIVE LYMPH NODES EXAMINED (0/5)

LEFT OBTURATOR/HYPOGASTRIC LYMPH NODES (O):

- NO MALIGNANCY IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

LEFT EXTERNAL ILIAC LYMPH NODES (P):

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODES EXAMINED (0/1)

LEFT PROXIMAL URETER (Q):

- HIGH GRADE URETER AND BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

RIGHT PROXIMAL URETER (R):

- BENIGN URETER
- NO UROTHELIAL DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT PRE SCIATIC LYMPH NODES (S):

- BENIGN FIBRO CONNECTIVE AND ADIPOSE TISSUE
- NO LYMPHOID TISSUE IDENTIFIED (0/0)

RIGHT PRE SCIATIC LYMPH NODES (T):

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODES EXAMINED (0/1)

LEFT URETER STENT [GROSS ONLY] (U):

- MEDICAL DEVICE, URETER STENT

LYMPH NODE SUMMARY: NO METASTATIC CARCINOMA IDENTIFIED IN TOTAL OF
54 LYMPH NODES EXAMINED (0/54)

BLADDER TNM STAGE: pt3bn0MX

Electronically signed by
Verified:

SPECIMEN SOURCE:

- A: "Rt distal ureter FS"
- B: "Lt distal stented ureter"
- C: "Lt unstented ureter"
- D: "Old scar perivesicle node, bladder, urethral margin, vagina strip"

[page 3 of 6]
SURGICAL PATHOLOGY REPORT

Collected

Ordered by

Location

E: "Left pelvic floor margin"
F: "Right para caval lymph nodes"
G: "Right common iliac lymph nodes"
H: "Right lymph node of cloquet"
I: "Left para aortic lymph nodes"
J: "Left common iliac lymph node"
K: "Right obturator/hypogastric lymph node"
L: "Right external iliac lymph node"
M: "Pre sacral lymph nodes"
N: "Left lymph node of cloquet"
O: "Left obturator/hypogastric lymph nodes"
P: "Left external iliac lymph nodes"
Q: "Left proximal ureter"
R: "Right proximal ureter"
S: "Left pre sciatic lymph nodes"
T: "Right pre sciatic lymph nodes"
U: "Left ureter stent"

CLINICAL INFORMATION:

Pre-op Dx: Bladder cancer

Post-op Dx: Same

GROSS EXAMINATION:

A: The specimen is received fresh from the O.R. and labeled "Rt distal ureter FS". It consists of two segments of ureter measuring in aggregate 1.5 x 0.5 x 0.3 cm. The specimen is entirely submitted for frozen section diagnosis in AFS.

B: The specimen is received fresh from the O.R. and labeled "Lt distal stented ureter". It consists of a segment of pink-tan ureter measuring 1 x 0.8 x 0.3 cm. The specimen is entirely submitted for frozen section diagnosis in BFS.

C: The specimen is received fresh from the O.R. and labeled "Lt unstented ureter". It consists of a segment of pink ureter measuring 0.6 x 0.3 x 0.2 cm. The specimen is entirely submitted for frozen section diagnosis in CFS.

D: The specimen is received fresh from the O.R. and labeled "Old scar perivesicle node, bladder, urethral margin, vaginal strip". It consists of a radical cystectomy specimen measuring overall 12 x 15 x 5 cm. A flap of peritoneum is present on the posterior surface measuring 23 x 9 x 1 cm. The peritoneum is smooth, mobile and glistening. The bladder itself measures 9 x 4 x 3 cm. There is an area marked by silk on the left wall. Opening the bladder reveals a large exophytic mass at the left ureterovesical junction measuring 3 x 2.5 x 4 cm in depth. Both ureterovesical junctions are identified and are patent. The attached ureters are identified and are opened. There are two ureters on either side. The right attached ureter (A) measures 5 cm in length x 0.6 cm in circumference and second right ureter (B) measures 4.5 cm in length x 0.6 cm in circumference. The left ureter (A) measures 6 cm in length x 1.2 cm in circumference and the second left ureter (B) measures 6 cm in length x 1.5 cm in circumference. The urethra measures 2.5 cm in length x 2.5 cm in circumference. The vaginal wall measures 4 x 3 x 0.2 cm. There is a skin ellipse measuring 15 x 1 x 0.3 cm. On the surface of the skin, there is a healed surgical scar measuring 10 cm in length. Representative sections are submitted in 29 cassettes.

E: The specimen is received in formalin and labeled "Left pelvic floor margin". It consists of segment of yellow lobulated fatty tissue measuring 3 x 2.4 x 0.2 cm. The specimen is entirely submitted in three cassettes.

F: The specimen is received in formalin and labeled "Right para caval lymph nodes". It consists of a segment of pale yellow lobulated fatty tissue measuring 2.9 x 2 x 0.2 cm. The specimen is entirely submitted in one cassette.

[page 4 of 6]
Collected
Ordered by

G: The specimen is received in formalin and labeled "Right common iliac lymph nodes". It consists of multiple pieces of pale yellow lobulated fatty tissue measuring in aggregate 2 x 1.7 x 0.6 cm. The specimen is entirely submitted in one cassette.

H: The specimen is received in formalin and labeled "Right lymph node of cloquet". It consists of multiple pieces of pale yellow lobulated fatty tissue measuring in aggregate 2.5 x 1.9 x 0.3 cm. The specimen is entirely submitted in two cassettes.

I: The specimen is received in formalin and labeled "Left para aortic lymph nodes". It consists of multiple pieces of pale yellow lobulated fatty tissue measuring in aggregate 1.5 x 0.9 x 0.2 cm. The specimen is entirely submitted in one cassette.

J: The specimen is received in formalin and labeled "Left common iliac lymph node". It consists of multiple pieces of pale yellow lobulated fatty tissue measuring in aggregate 2.5 x 1.6 x 1 cm. The specimen is entirely submitted in three cassettes.

K: The specimen is received in formalin and labeled "Right obturator/hypogastric lymph node". It consists of multiple pieces of pale yellow lobulated fatty tissue measuring in aggregate 6.5 x 4 x 1 cm. The specimen is entirely submitted in five cassettes.

L: The specimen is received in formalin and labeled "Right external iliac lymph node". It consists of multiple pieces of pale yellow lobulated fatty tissue measuring in aggregate 4.5 x 3 x 1 cm. The specimen is entirely submitted in one cassette.

M: The specimen is received in formalin and labeled "Pre sacral lymph nodes". It consists of a segment of yellow lobulated fatty tissue measuring 4.5 x 3 x 0.2 cm. The specimen is entirely submitted in three cassettes.

N: The specimen is received in formalin and labeled "Left lymph node of cloquet". It consists of multiple pieces of pale yellow lobulated fatty tissue measuring in aggregate 2.6 x 2.5 x 0.5 cm. The specimen is entirely submitted in two cassettes.

O: The specimen is received in formalin and labeled "Left obturator/hypogastric lymph nodes". It consists of multiple pieces of pale yellow lobulated fatty tissue measuring in aggregate 2.5 x 2 x 0.2 cm. The specimen is entirely submitted in two cassettes.

P: The specimen is received in formalin and labeled "Left external iliac lymph nodes". It consists of multiple pieces of pale yellow lobulated fatty tissue measuring in aggregate 3 x 3 x 0.5 cm. The specimen is entirely submitted in three cassettes.

Q: The specimen is received in formalin and labeled "Left proximal ureter". It consists of two segments of ureter measuring 0.7 cm in diameter x 0.7 cm in length and 0.5 cm in diameter x 0.5 cm in length. The largest segment of ureter has a black suture around it. The larger segment is inked black. Specimen is entirely submitted in two cassettes.

R: The specimen is received in formalin and labeled "Right proximal ureter". It consists of two segments of ureter, each measuring 0.2 cm in diameter x 0.5 cm in length. The specimen is entirely submitted in one cassette.

S: The specimen is received in formalin and labeled "Left pre sciatic lymph nodes". It consists of multiple pieces of pale yellow lobulated fatty tissue

[page 5 of 6]
SURGICAL PATHOLOGY REPORT

Collected
Ordered by

Location

measuring in aggregate 2.5 x 1.5 x 0.3 cm. The specimen is entirely submitted in one cassette.

T: The specimen is received in formalin and labeled "Right pre sciatic lymph nodes". It consists of multiple pieces of pale yellow lobulated fatty tissue measuring in aggregate 2 x 2.2 x 0.5 cm. The specimen is entirely submitted in two cassettes.

U: The specimen is received in a plastic container and labeled "Left ureter stent". It consists of a plastic tubing measuring 35 cm in length with an average diameter of 0.2 cm. Gross description only.

SECTIONS:

AFS: frozen section, right distal ureter
BFS: frozen section, left distal stented ureter
CFS: frozen section, left unstented ureter
D1: urethral margin
D2: right vaginal margin
D3: distal vaginal margin
D4: left vaginal margin
D5: right proximal ureter margin of specimen
D6: left proximal ureter margin of specimen
D7: right ureterovesical junction (A)
D8: right ureterovesical junction (B)
D9: cross section of ureters (A and B)
D10: left ureterovesical junction with tumor involvement (left A)
D11: left ureter (B) junction opening into left ureter (A)
D12: mid section of left ureter
D13: cross section of proximal left ureter
D14-17: deep margin of tumor
D18: trigone
D19: bladder neck, proximal urethra
D20: posterior wall of bladder
D21: dome of bladder
D22: surface of tumor with bladder junction
D23, 24: right perivesical fat for probable lymph nodes
D25-28: left perivesical fat for probable lymph nodes
D29: representative of skin
E1-3: left pelvic floor margin
F: right para caval lymph nodes
G: right common iliac lymph nodes
H1-2: right lymph node of Cloquet
I: left para aortic lymph nodes
J1-3: left common iliac lymph node
K1-5: right obturator/hypogastric lymph node
L: right external iliac lymph node
M1-3: pre sacral lymph nodes
N1-2: left lymph node of Cloquet
O1-2: left obturator/hypogastric lymph nodes
P1-3: left external iliac lymph nodes
Q1: left proximal ureter; larger segment
Q2: smaller segment
R: right proximal ureter
S: left pre sciatic lymph nodes
T: right pre sciatic lymph nodes

[page 6 of 6]
SURGICAL PATHOLOGY REPORT

Collected

Ordered by

Location

INTRAOPERATIVE FROZEN CONSULTATION:

- AFS: Right distal ureter
- no tumor identified
- BFS: Left distal stented ureter
- hydroureter
- no tumor identified
- CFS: Left unstented ureter
- reactive atypia
- no high-grade dysplasia identified

INTRAOPERATIVE GROSS CONSULTATION

- Exophytic mass at left uretero-vesical junction. Dual ureters entering bladder on both sides.

MICROSCOPIC EXAMINATION:

A-U: See final microscopic-diagnosis.

Source: NCI Genomic Data Commons file 693c53f5-40ee-4f5a-b3ff-80205d313467 (TCGA-XF-AAN8.07718E82-778A-4797-BBAD-4494AAE3CAA2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).